Somatic mutation profile of tumor specimen TCGA-HT-7608-01A (aliquot TCGA-HT-7608-01A-11D-2086-08) from TCGA case TCGA-HT-7608, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 61.1 years (22,302 days).
Specimen TCGA-HT-7608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4770b12-5225-4fff-9d1c-3cd5d85eed77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7608-10A (Blood Derived Normal), aliquot TCGA-HT-7608-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/652053e9-fdbf-45d9-9731-0109a2844ab4

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/114 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TSHR | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201889708, COSV53317507; ClinVar: benign / uncertain significance / likely pathogenic; called by muse, mutect2
- AP1S1 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV61760902; called by muse, mutect2
- CACNA1F | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59906719; called by muse, mutect2
- CCDC185 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs748509441, COSV64821774; called by muse, mutect2, varscan2
- IL17F | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs569473195, COSV60235161; called by muse, mutect2, varscan2
- LMNA | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV61543947; called by muse, mutect2, varscan2
- MYH8 | c.4603C>T p.Q1535* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV67971438; called by muse, mutect2, varscan2
- NF1 | c.3719C>G p.A1240G | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV62204386, COSV62218662; called by muse, mutect2
- OTOP1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs537569170, COSV56393346; called by muse, mutect2, varscan2
- TOP3B | c.738+1G>T p.X246_splice | Splice Site (SNP) | VAF 22/92 reads (24%) | catalogued as COSV64119035; called by muse, mutect2, varscan2
- BTBD1 | c.1290+2_1290+5del p.X430_splice | Splice Site (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- CIC | c.825_826del p.K276Vfs*38 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- DESI1 | c.19dup p.Y7Lfs*41 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- FUBP1 | c.1693dup p.T565Nfs*2 | Frame Shift Ins (INS) | VAF 41/90 reads (46%) | called by mutect2, pindel, varscan2
- KLHL25 | c.390C>T p.H130= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs766148345, COSV61996299; called by muse, mutect2, varscan2
- PRPF40B | c.2025C>G p.L675= (on ENST00000380281; = p.L662= on NM_012272.3) | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV53306992; called by muse, mutect2, varscan2
- RASD2 | c.678C>T p.D226= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs144245051; called by muse, mutect2, varscan2
- TIGIT | c.618A>G p.A206= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as COSV67329445; called by muse, mutect2, varscan2
